Somatic mutation profile of tumor specimen C3L-00461-34 (aliquot CPT0054280002) from CPTAC case C3L-00461, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.8 years (25,865 days).
Specimen C3L-00461-34: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdbbd207-140c-4c2f-8cda-709b9574a64f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00461-52 (Buccal Cell Normal), aliquot CPT0054300005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cc060f0-9a5b-40b1-84d0-922b5717de57

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 3, Intron 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 25/64 reads (39%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FAAP24 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs555157808, COSV99577755, COSV99578062; called by muse, varscan2
- LRIF1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751118502, COSV63897200; called by muse, mutect2
- MYH1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761496068; called by muse, mutect2, varscan2
- PTPN3 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.521); catalogued as rs1412097270; called by muse, mutect2
- TRPV4 | c.2209-4G>A | Splice Region (SNP) | VAF 87/223 reads (39%) | catalogued as rs762947389; called by muse, mutect2, varscan2
- ADAMTS6 | c.2624T>C p.I875T | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP11A1 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GSS | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MGARP | c.676dup p.Q226Pfs*9 | Frame Shift Ins (INS) | VAF 20/176 reads (11%) | called by mutect2, pindel
- MYO16 | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDS5B | c.2375dup p.I793Hfs*9 | Frame Shift Ins (INS) | VAF 59/169 reads (35%) | called by mutect2, pindel, varscan2
- DEF6 | c.210C>G p.P70= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV100359292; called by muse, mutect2, varscan2
- FUNDC2 | c.520C>T p.L174= | Silent (SNP) | VAF 79/98 reads (81%) | called by muse, mutect2, varscan2
- NEK8 | c.498C>T p.T166= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- NSD3 | c.3942A>G p.T1314= | Silent (SNP) | VAF 124/350 reads (35%) | called by muse, varscan2
- DOT1L | c.4606+1113G>A | Intron (SNP) | VAF 83/216 reads (38%) | catalogued as rs1310094809; called by muse, varscan2
- DOT1L | c.4606+1114C>T | Intron (SNP) | VAF 82/216 reads (38%) | catalogued as rs1436602814, COSV58537056; called by muse, varscan2
- SLC16A10 | c.942+13C>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
